Surgical pathology report (de-identified scan), TCGA case TCGA-ZF-AA4V, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Sheffield, specimen TCGA-ZF-AA4V-01A (Primary Tumor).

[page 1 of 2]
Histopathology Histopathology

Specimen Comments

SPECIMEN

1. Right external iliac node anterior.
2. Right external iliac node common.
3. Right external iliac node posterior.
4. Right internal iliac.
5. Right obturator.
6. Left external iliac anterior.
7. Left external iliac posterior.
8. Left obturator node.
9. Left common iliac.
10. Left ureteric margin.
11. Right ureteric margin.
12. Cystectomy + lymphadenectomy

CLINICAL DETAILS

Radical cystectomy for invasive bladder cancer + lymphadenectomy. G3 T2 at

CCF
ICD-O-3
Carcinoma, urothelial NOS 8120/3
Carcinoma, transitional cell NOS 8120/3
Site: Bladder NOS C67.9
JAD 4/30/14

MACROSCOPY

1. Fatty tissue measuring 45x30x5 mm. No lymph node identified.
2. Fatty tissue measuring 100x20x20 mm.
3. Fatty tissue measuring 30x25x15 mm.
4. Fatty tissue measuring 40x35x25 mm.
5. Fatty tissue measuring 65x35x20 mm.
6. Fatty tissue measuring 50x25x15 mm.
7. Fatty tissue measuring 80x20x15 mm.
8. Fatty tissue measuring 70x30x20 mm.
9. Fatty tissue measuring 35x25x20 mm.
10. Tissue measuring 9 mm max.
11. Tissue measuring up to 10 mm.
12. Specimen overall measures 115 mm superior-inferior x 120 mm medial-lateral x 55 mm anterior-posterior. Bladder measures 95 mm superior-inferior x 60 mm medial-lateral x 50 mm anterior-posterior. Prostate measures up to 45 mm. At the dome of the bladder on the anterior surface, there is a solid exophytic mass measuring 45 mm in dimension and up to 20 mm in depth.

MICROSCOPY

1. Right external iliac anterior - no lymph nodes identified.
2. Right external iliac common - two lymph nodes identified, showing no evidence of metastasis.
3. Right external iliac posterior - three lymph nodes identified, showing no evidence of metastasis.
4. Right internal iliac - two lymph nodes identified, showing no evidence of metastasis.
5. Right obturator - three lymph nodes identified, showing no evidence of metastasis.
6. Left external iliac anterior - two lymph nodes identified, showing no evidence of metastasis.
7. Left external iliac posterior - three lymph nodes identified, showing no

[page 2 of 2]
evidence of metastasis.

8. Left obturator node - three lymph nodes identified, showing no evidence of metastasis.

9. Left common iliac - 2 lymph nodes identified, showing no evidence of metastasis.

10&11. Left and right ureteric margins are normal, with no evidence of dysplasia or malignancy.

12. Sections show a poorly differentiated, grade 3 transitional cell carcinoma of the bladder. It invades the entire depth of the muscularis propria and infiltrates perivesical fat. It has a 'pushing' rather than infiltrative growth pattern, with a moderate lymphocytic response. The circumferential and urethral margins are clear. Adjacent urothelium shows no evidence of dysplasia.

Representative sections of prostate show no significant abnormality.

SUMMARY

Transitional cell carcinoma of the bladder G3 pT3 pN0 pMx.

Ref:

Pathologists -

Source: NCI Genomic Data Commons file 34bc766f-dfc4-44c8-98ed-38b2ff20b215 (TCGA-ZF-AA4V.52B54951-E580-49D6-BBB5-4F2329A271B0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).